TARGET case TARGET-15-SJMPAL042797 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5b31812e-eb04-4b6e-a2e5-c8123a7ca9f4

Demographics
Sex at birth: female; Age at index: 6 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 6.1 years (2,238 days); Year of diagnosis: 2005; Days to last follow up: 3,535 days (9.7 years).

Follow-up (1 entry)
- Days to follow up: 3,535 days (9.7 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,535; Year of follow up: 2015.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 58.8 ×10³/µL.

Biospecimens (1 sample)
- Sample TARGET-15-SJMPAL042797-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 3535
- Protocol: Japan (TCCSG)
- WBC at Diagnosis: 58.8
- Initial Therapy: AML
- Karyotype: 46,XX,add(1)(p32),inv(1)(p36q32),del(4)(q?),del(11)(q?),add(12)(p13),del(16)(q12)
- WHO ALAL Classification: T/M
- WHO Dx: T/M
